CCDI case PBCBUW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ad66826c-fe49-426b-a300-1d459396fbcf

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 0.7 years (252 days).

Biospecimens (3 samples)
- Sample 0DNKZE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNKZJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DNKZO: Tissue type: Tumor; Specimen type: Solid Tissue.
